Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4342, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4342-01A (Primary Tumor).

[page 1 of 2]
Patient Name

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

tion:
ice:

Clinical Diagnosis & History:

male with a kidney tumor, left. Past medical history of bladder cancer ✓

Specimens Submitted:

- 1: SP: Left kidney and adrenal
- 2: SP: Para-aortic lymph nodes
- 3: SP: Part of the left kidney

DIAGNOSIS:

- 1) KIDNEY, LEFT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 11 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- INVASION OF THE RENAL VEIN IS PRESENT.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS UNREMARKABLE.
- THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): ONE BENIGN PERINEPHRITIC LYMPH NODE (0/1).
- 2) LYMPH NODES, PARA-AORTIC; EXCISION:
- SIX BENIGN LYMPH NODES (0/6).
- 3) KIDNEY, PART OF LEFT; EXCISION:
- FRAGMENT OF ADIPOSE TISSUE.
- NO TUMOR SEEN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh and sterile, labeled, "Left kidney and adrenal". It consists of a nephrectomy specimen with attached perinephric adipose tissue. The specimen measures 30.0 x 18.0 x 10.0 cm. The specimen is bisected to reveal a hemorrhagic, yellowish mass located in the superior aspect of the kidney, measuring 11.0 x 9.0 x 5.0 cm, which extends just underneath the kidney capsule and grossly confined into the capsule. There is another tan-white cyst located at the inferior portion of the kidney, measuring 5.0 x 4.0 x 3.0 cm with a smooth internal surface and is also confined into the renal capsule. About 80% of the renal parenchyma is replaced by the mass and the remaining kidney parenchyma measures 5.0 x 3.0 x 3.0 cm. The resection margin of the renal vein and ureter are identified, grossly unremarkable. Sectioning of the tumor displays yellowish-brown, hemorrhagic cut surface with focal necrosis. The tumor involves the pelvis and renal vein grossly. Sectioning of

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

the remaining renal parenchyma is tan-brown and unremarkable. The adrenal gland is identified, measuring about 3.0 x 2.0 x 0.6 cm. Sectioning of the perinephric fatty tissue is unremarkable. No definite lymph nodes are identified. Representative sections from the ureter, vascular margin, from the tumor, renal parenchyma and adrenal gland are submitted.

Summary of Sections:

UM – ureteral margin

VM – vascular margin

AD – adrenal gland

T – tumor section

U – undesignated renal parenchyma

F – fatty tissue

2) The specimen is received in formalin, labeled, "Para-aortic lymph nodes". It consists of two fragments of fatty tissue, measuring 5.0 x 5.0 x 2.5 cm and sectioning reveals multiple lymph nodes, measuring 0.3 up to 1.0 cm in greatest dimension. The entire lymph nodes are submitted.

Summary of Sections:

LN – lymph nodes

3) The specimen is received fresh, labeled, "Part of the left kidney". It consists of a fragment of adipose tissue, measuring 20.0 x 9.0 x 1.5 cm. Serial sectioning reveals mature adipose tissue. No nodules in the renal parenchyma are identified. Representative sections are submitted.

Summary of Sections:

F – fatty tissue

Summary of Sections:

Part 1: SP: Left kidney and adrenal

Block	Sect. Site	PCs
1	AD	1
1	F	1
10	S	10
1	U	1
1	UM	1
1	VM	1

Part 2: SP: Para-aortic lymph nodes (pjm)

Block	Sect. Site	PCs
4	LN	4

Part 3: SP: Part of the left kidney (pjm)

Block	Sect. Site	PCs
1	F	1

Source: NCI Genomic Data Commons file 31be19ad-68f1-4a8b-90ec-7c958c4156ad (TCGA-BP-4342.5B0089D3-216A-4385-8BD3-2B86A5ADD75C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).